Somatic mutation profile of tumor specimen MMRF_1401_2_BM_CD138pos (aliquot MMRF_1401_2_BM_CD138pos_T1_KHS5U_L08120) from MMRF case MMRF_1401, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.9 years (30,263 days).
Specimen MMRF_1401_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 491dec5b-f55d-4262-aeec-f8dd2d15ed25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1401_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1401_1_PB_Whole_C2_KAS5U_L01932; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4760a77d-6846-40ea-97fc-616b9ff423d8

The open-access MAF lists 106 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 31, Intron 13, Silent 9, 5'UTR 7, Nonsense Mutation 5, 5'Flank 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2B | c.5113C>T p.R1705* | Nonsense Mutation (SNP) | VAF 10/156 reads (6%) | catalogued as rs1555731976, COSV55862100; ClinVar: pathogenic; called by muse, mutect2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 47/51 reads (92%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, varscan2
- FAM117B | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as rs774669794, COSV57419630; called by muse, mutect2, varscan2
- IGLV4-60 | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 69/70 reads (99%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs536416304; called by muse, mutect2, varscan2
- LRRC7 | c.4359G>T p.Q1453H (on ENST00000651989 / NM_001370785.2; = p.Q1373H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99224388; called by mutect2, varscan2
- MAGEL2 | c.3158A>T p.E1053V | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs765345034; called by muse, mutect2, varscan2
- MAIP1 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99705331; called by muse, mutect2, varscan2
- MEGF8 | c.8368G>A p.G2790R (on ENST00000251268 / NM_001271938.2; = p.G2723R on NM_001410.3) | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776276340, COSV52096959; called by muse, varscan2
- OR4P4 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs754516549; called by muse, mutect2, varscan2
- PGM1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs754131603, COSV64300610; called by muse, mutect2, varscan2
- SHISA3 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1454272136; called by muse, mutect2, varscan2
- SLITRK3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV53846738; called by muse, mutect2, varscan2
- TRAM1L1 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs992203106; called by muse, mutect2
- UNC93B1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as rs752295686; called by muse, mutect2, varscan2
- ZIC1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1461615959, COSV51555489; called by muse, mutect2, varscan2
- ZKSCAN1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1355735435; called by muse, mutect2, varscan2
- ABI1 | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APBA1 | c.1337-2A>G p.X446_splice | Splice Site (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- C22orf39 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- CD44 | c.1649C>G p.S550C | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CDHR2 | c.1268C>G p.A423G | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- COL6A5 | c.4291G>A p.G1431R | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOP1B | c.2942del p.G981Afs*76 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- DUSP7 | c.1104_1114dup p.F372Sfs*20 | Frame Shift Ins (INS) | VAF 38/102 reads (37%) | called by mutect2, varscan2
- FAM124A | c.787G>C p.G263R (on ENST00000322475 / NM_001242312.2; = p.G299R on NM_145019.4) | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM1 | c.2790_2793del p.R932Nfs*7 | Frame Shift Del (DEL) | VAF 56/178 reads (31%) | called by mutect2, pindel, varscan2
- FREM2 | c.1772C>A p.S591* | Nonsense Mutation (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- HTR3C | c.1015C>G p.Q339E | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- IGLV1-51 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, varscan2
- IGSF10 | c.6110C>G p.P2037R | Missense Mutation (SNP) | VAF 100/207 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ITGAX | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- NOTCH3 | c.5341G>A p.D1781N | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NOX4 | c.1436T>A p.L479* | Nonsense Mutation (SNP) | VAF 17/221 reads (8%) | called by muse, mutect2
- NTRK2 | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8B8 | c.807_809del p.N269_Q270delinsK | In Frame Del (DEL) | VAF 64/190 reads (34%) | called by mutect2, pindel, varscan2
- PCDHA6 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGM2L1 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 113/372 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- PKN3 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRDM15 | c.2159A>T p.Y720F | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- RNGTT | c.177T>G p.V59= | Splice Region (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2
- STARD9 | c.13255T>A p.S4419T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- ZNF568 | c.1208C>G p.S403* | Nonsense Mutation (SNP) | VAF 47/91 reads (52%) | called by muse, mutect2, varscan2
- H3C12 | c.255C>T p.F85= | Silent (SNP) | VAF 11/148 reads (7%) | called by muse, mutect2
- IGSF5 | c.1167A>G p.P389= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- IQUB | c.1402T>C p.L468= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as rs1296002931; called by muse, mutect2
- MEP1B | c.690C>T p.D230= | Silent (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- NCS1 | c.321C>G p.L107= | Silent (SNP) | VAF 36/136 reads (26%) | called by muse, mutect2, varscan2
- NFXL1 | c.2193G>A p.Q731= | Silent (SNP) | VAF 67/145 reads (46%) | called by muse, mutect2, varscan2
- PRDM13 | c.186C>T p.G62= | Silent (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- STARD9 | c.660C>T p.A220= | Silent (SNP) | VAF 79/201 reads (39%) | catalogued as rs1206410526; called by muse, mutect2, varscan2
- THBD | c.126C>T p.P42= | Silent (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- AAGAB | c.*1044T>C | 3'UTR (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- ADM2 | c.-11-9C>T | Intron (SNP) | VAF 20/38 reads (53%) | catalogued as rs771526212; called by muse, mutect2, varscan2
- ANKHD1 | c.-135A>T | 5'UTR (SNP) | VAF 17/47 reads (36%) | called by mutect2, varscan2
- BAIAP2 | c.1535+679C>T | Intron (SNP) | VAF 29/53 reads (55%) | catalogued as rs1378303543; called by muse, mutect2, varscan2
- BEST3 | c.*8A>G | 3'UTR (SNP) | VAF 124/276 reads (45%) | called by muse, mutect2, varscan2
- CAPRIN2 | c.-591G>A | 5'UTR (SNP) | VAF 116/266 reads (44%) | called by muse, mutect2, varscan2
- CD164 | c.*407A>G | 3'UTR (SNP) | VAF 31/68 reads (46%) | catalogued as rs575312893; called by muse, mutect2, varscan2
- CDHR1 | c.*2468G>T | 3'UTR (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- CHRNB1 | c.462+44C>T | Intron (SNP) | VAF 80/183 reads (44%) | called by muse, mutect2, varscan2
- CIZ1 | c.*70A>G | 3'UTR (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- CNPY2 | c.-25-176G>A | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, varscan2
- COA1 | c.-38-489A>C | Intron (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- CREBRF | c.*3517G>C | 3'UTR (SNP) | VAF 59/109 reads (54%) | called by muse, mutect2, varscan2
- CREBRF | c.*4750G>T | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, varscan2
- CREBRF | c.*5340G>A | 3'UTR (SNP) | VAF 29/56 reads (52%) | called by mutect2, varscan2
- CTNND1 | c.*1590A>G | 3'UTR (SNP) | VAF 74/577 reads (13%) | called by muse, mutect2, varscan2
- DACH2 | c.1751-519A>C | Intron (SNP) | VAF 36/38 reads (95%) | called by muse, mutect2, varscan2
- DAND5 | c.*25G>A | 3'UTR (SNP) | VAF 39/78 reads (50%) | catalogued as rs375137580; called by muse, mutect2, varscan2
- EMB | c.*2641T>C | 3'UTR (SNP) | VAF 78/379 reads (21%) | called by muse, mutect2, varscan2
- FAM13A | c.605+34A>C | Intron (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- FAM98B | c.*1470A>G | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- FAT3 | c.*3883A>G | 3'UTR (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- FBN2 | c.4471+495T>A | Intron (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- GABRA4 | c.*5426T>C | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- GLB1L2 | c.*523T>A | 3'UTR (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
- GMCL1 | c.*1643G>A | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2
- GORAB | c.662+369G>T | Intron (SNP) | VAF 24/35 reads (69%) | called by muse, mutect2, varscan2
- IDI1 | c.140+378G>A | Intron (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2
- IGF1R | c.*2760G>C | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- KLF4 | c.-10C>A | 5'UTR (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- KRBA2 | c.*203G>A | 3'UTR (SNP) | VAF 15/32 reads (47%) | catalogued as rs549192093; called by muse, mutect2, varscan2
- MSL3 | c.1171+241C>T | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- MTHFD2 | chr2:74198614 C>G | 5'Flank (SNP) | VAF 27/66 reads (41%) | catalogued as rs112453409; called by muse, mutect2, varscan2
- NAALAD2 | c.*464T>G | 3'UTR (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- NR2F1 | c.-1047C>T | 5'UTR (SNP) | VAF 48/48 reads (100%) | called by muse, mutect2, varscan2
- PDE7B | c.*2134G>T | 3'UTR (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- PFAS | c.*213G>T | 3'UTR (SNP) | VAF 52/109 reads (48%) | catalogued as rs915376771; called by muse, mutect2, varscan2
- PGRMC2 | c.*1024G>A | 3'UTR (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.*1887G>A | 3'UTR (SNP) | VAF 26/55 reads (47%) | catalogued as rs1008440189; called by muse, mutect2, varscan2
- PLXNA4 | c.*6041C>G | 3'UTR (SNP) | VAF 70/167 reads (42%) | called by muse, varscan2
- PPP3CA | c.-337G>C | 5'UTR (SNP) | VAF 78/143 reads (55%) | called by mutect2, varscan2
- PTPN20 | chr10:47001902 C>A | 3'Flank (SNP) | VAF 19/191 reads (10%) | called by muse, mutect2
- RAET1E | c.622+213C>A | Intron (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- RASA3 | c.*1048A>C | 3'UTR (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- RCOR1 | c.*1265A>G | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- SCN3B | c.*6G>A | 3'UTR (SNP) | VAF 44/400 reads (11%) | called by muse, mutect2, varscan2
- SLAMF1 | chr1:160647066 C>T | 5'Flank (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- SLC6A2 | c.*1340G>A | 3'UTR (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- SNAP23 | c.*147T>G | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- SNX21 | c.*729A>G | 3'UTR (SNP) | VAF 62/125 reads (50%) | called by muse, mutect2, varscan2
- SSBP2 | c.-10C>T | 5'UTR (SNP) | VAF 109/248 reads (44%) | catalogued as rs745699701; called by muse, mutect2, varscan2
- TMEM184C | c.-552C>G | 5'UTR (SNP) | VAF 29/46 reads (63%) | called by muse, mutect2, varscan2
- ZC3H7A | c.*602C>G | 3'UTR (SNP) | VAF 29/76 reads (38%) | catalogued as rs990318293, COSV100865632; called by muse, mutect2, varscan2
- ZC3H7A | c.*463C>G | 3'UTR (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- ZNF595 | c.226+7985T>A | Intron (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
